Gene-level copy-number profile of tumor specimen TCGA-CV-7100-01A from TCGA case TCGA-CV-7100, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.2 years (24,183 days).
Specimen TCGA-CV-7100-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.36b812e7-2cb9-40c2-97c1-320173a9173d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7100-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/430e1720-7a5a-4c16-854a-1a69af0fab05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,128; copy number 2: 46,141; copy number 3: 2,526; copy number 4: 329; copy number 5: 647; copy number 6: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7100-01A-11D-2010-01): tumor purity 0.59, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 692 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,222,513, 645 genes, copy number 5 (broad region; genes not listed).
- chr11:15,112,424–15,481,893, 2 genes, copy number 5 (within-gene range 3–5): INSC, AC104361.1.
- chr12:32,339,368–32,646,050, 5 genes, copy number 6 (within-gene range 4–6): AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr19:16,161,368–16,892,606, 40 genes, copy number 6: CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2, KLF2, AC020917.3, EPS15L1, AC020917.4, AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3.

Autosomal genes at a single copy (total copy number 1): 7,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
